Somatic mutation profile of tumor specimen TCGA-CG-5725-01A (aliquot TCGA-CG-5725-01A-11D-1600-08) from TCGA case TCGA-CG-5725, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 72.1 years (26,329 days).
Specimen TCGA-CG-5725-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7549039e-2c47-4582-ba3e-5e16dc8528f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-5725-11A (Solid Tissue Normal), aliquot TCGA-CG-5725-11A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2415877f-0015-4d05-bedf-3c738c095526

The open-access MAF lists 107 somatic variants for this specimen: 96 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Frame Shift Ins 26, Frame Shift Del 22, In Frame Del 9, Splice Site 5, Silent 5, In Frame Ins 2, Nonsense Mutation 2, Splice Region 2, 5'UTR 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.3221G>T p.C1074F | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99713523; called by muse, mutect2, varscan2
- AC100868.1 | c.1420G>T p.V474F | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as rs751617233, COSV99226395; called by muse, mutect2
- ADGRB3 | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs1338093306, COSV101001112; called by muse, mutect2, varscan2
- AGXT2 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99183785; called by muse, mutect2, varscan2
- BMS1 | c.2207G>A p.R736K | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs372564970, COSV100996754; called by muse, mutect2, varscan2
- CASKIN2 | c.2974C>T p.R992W | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777511333, COSV100050636; called by muse, mutect2, varscan2
- CBLL2 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 51/60 reads (85%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100081656; called by muse, mutect2, varscan2
- CDC123 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs913696153, COSV99827042; called by muse, mutect2
- CPSF2 | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.086); catalogued as COSV54097819; called by muse, mutect2, varscan2
- GCC2 | c.1322A>G p.N441S | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1257604297, COSV100565534; called by muse, mutect2, varscan2
- GLT6D1 | c.107G>T p.W36L | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs776370434, COSV100874557; called by muse, mutect2, varscan2
- H2AW | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs754510222, COSV100797293; called by muse, mutect2, varscan2
- HMG20A | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.046); catalogued as COSV100287845, COSV60311249; called by muse, mutect2, varscan2
- IFIT3 | c.693A>C p.E231D | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV99260638; called by muse, mutect2, varscan2
- KDM4A | c.2473C>T p.R825C | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1375643320, COSV99071843; called by muse, mutect2, varscan2
- KIF5A | c.2254C>A p.L752M | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV99673216; called by muse, mutect2, varscan2
- LONP1 | c.2764G>A p.D922N | Missense Mutation (SNP) | VAF 66/89 reads (74%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); catalogued as rs139476430, COSV100028645; called by muse, mutect2, varscan2
- NPAP1 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 37/42 reads (88%) | SIFT tolerated (0.23); PolyPhen benign (0.438); catalogued as rs1277274517, COSV61505858; called by muse, mutect2, varscan2
- NR5A1 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs769207009, CM156317, COSV65294583; called by muse, mutect2, varscan2
- PAQR9 | c.523_524insC p.Y175Sfs*202 | Frame Shift Ins (INS) | VAF 9/55 reads (16%) | catalogued as COSV100503863; called by mutect2, pindel, varscan2
- PCDHGC5 | c.902C>A p.A301E | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99341191; called by muse, mutect2
- SENP6 | c.1205A>C p.K402T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100519328; called by muse, mutect2
- SLC25A47 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV100836543, COSV64161453, COSV64162063; called by muse, mutect2, varscan2
- TANC2 | c.5561G>A p.R1854Q | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV101267576; called by muse, mutect2, varscan2
- TBC1D31 | c.226T>G p.F76V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99782955; called by muse, mutect2, varscan2
- THBS1 | c.3235G>A p.A1079T | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376857586; called by muse, mutect2, varscan2
- TMEM104 | c.245T>G p.L82R | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100120547; called by muse, mutect2, varscan2
- TOP2A | c.2229G>T p.K743N | Missense Mutation (SNP) | VAF 112/264 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV70732591; called by muse, varscan2
- ZNF195 | c.1210G>T p.E404* (on ENST00000399602 / NM_001130520.3; = p.E332* on NM_007152.5) | Nonsense Mutation (SNP) | VAF 107/136 reads (79%) | catalogued as COSV50007907, COSV99138004; called by muse, mutect2, varscan2
- ZNF536 | c.3298G>A p.V1100M | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200453890, COSV62825016; called by muse, mutect2, varscan2
- AASDH | c.387_391dup p.T131Mfs*11 | Frame Shift Ins (INS) | VAF 18/58 reads (31%) | called by mutect2, varscan2
- ABCA12 | c.4977_4977+2del p.X1659_splice (on ENST00000272895 / NM_173076.3; = p.X1341_splice on NM_015657.3) | Splice Site (DEL) | VAF 43/97 reads (44%) | called by mutect2, pindel, varscan2
- ACACB | c.2685_2689del p.V896Efs*20 | Frame Shift Del (DEL) | VAF 51/62 reads (82%) | called by mutect2, pindel, varscan2
- ACBD5 | c.171dup p.N58Efs*9 (on ENST00000375888 / NM_001352568.1; = p.N60Efs*9 on NM_145698.5 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 27/79 reads (34%) | called by mutect2, pindel, varscan2
- ACSS1 | c.1257dup p.I420Hfs*4 | Frame Shift Ins (INS) | VAF 21/64 reads (33%) | called by mutect2, pindel, varscan2
- ARPP21 | c.36del p.E13Rfs*53 | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | called by mutect2, pindel, varscan2
- ASPM | c.725_737del p.R242Pfs*14 | Frame Shift Del (DEL) | VAF 40/198 reads (20%) | called by mutect2, pindel, varscan2
- BRD3 | c.1666_1696del p.Q556Rfs*7 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | called by mutect2, pindel
- CACNA1D | c.5435_5435+14del p.X1812_splice (on ENST00000350061 / NM_001128840.3; = p.X1832_splice on NM_000720.4) | Splice Site (DEL) | VAF 30/59 reads (51%) | called by mutect2, pindel, varscan2
- CACNA1D | c.6297_6313del p.M2099Ifs*4 (on ENST00000350061 / NM_001128840.3; = p.M2119Ifs*4 on NM_000720.4) | Frame Shift Del (DEL) | VAF 5/60 reads (8%) | called by mutect2, pindel
- CELF1 | c.116_119del p.Y39Lfs*9 | Frame Shift Del (DEL) | VAF 60/174 reads (34%) | called by mutect2, pindel, varscan2
- CFAP52 | c.305_306dup p.L103Sfs*28 | Frame Shift Ins (INS) | VAF 23/40 reads (58%) | called by mutect2, pindel, varscan2
- DHX15 | c.2370_2371dup p.E791Gfs*11 | Frame Shift Ins (INS) | VAF 17/57 reads (30%) | called by mutect2, pindel, varscan2
- DIAPH1 | c.2473+1_2473+3del p.X825_splice | Splice Site (DEL) | VAF 43/57 reads (75%) | called by mutect2, pindel, varscan2
- DOK2 | c.983dup p.L329Sfs*6 | Frame Shift Ins (INS) | VAF 39/161 reads (24%) | called by mutect2, pindel, varscan2
- DYSF | c.2050_2051insAGCC p.R684Qfs*33 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- FZD8 | c.121_128del p.P41* | Frame Shift Del (DEL) | VAF 17/37 reads (46%) | called by mutect2, pindel, varscan2
- GGCX | c.1753_1758del p.E585_Y586del | In Frame Del (DEL) | VAF 65/153 reads (42%) | called by mutect2, pindel, varscan2
- HDAC4 | c.673_682del p.Y225Rfs*23 | Frame Shift Del (DEL) | VAF 21/82 reads (26%) | called by mutect2, pindel, varscan2
- HLA-E | c.1021dup p.Y341Lfs*3 | Frame Shift Ins (INS) | VAF 46/152 reads (30%) | called by mutect2, pindel, varscan2
- IFIH1 | c.2252_2258del p.A751Vfs*2 | Frame Shift Del (DEL) | VAF 47/68 reads (69%) | called by mutect2, pindel, varscan2
- KAT5 | c.172dup p.V58Gfs*4 | Frame Shift Ins (INS) | VAF 39/109 reads (36%) | called by mutect2, pindel, varscan2
- KCMF1 | c.134_142del p.R45_T47del | In Frame Del (DEL) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- KCNK7 | c.261_262insCTGC p.R88Lfs*172 (on ENST00000340313 / NM_033347.2; = p.R88Lfs*155 on NM_005714.2) | Frame Shift Ins (INS) | VAF 5/18 reads (28%) | called by mutect2, varscan2
- KRT10 | c.1013_1015del p.A338_W339delinsG | In Frame Del (DEL) | VAF 30/126 reads (24%) | called by mutect2, pindel*, varscan2
- LXN | c.20_23dup p.Y8* | Nonsense Mutation (INS) | VAF 26/146 reads (18%) | called by mutect2, pindel, varscan2
- LYST | c.7301_7306del p.I2434_E2435del | In Frame Del (DEL) | VAF 57/154 reads (37%) | called by mutect2, pindel, varscan2
- MAP3K6 | c.3318_3320dup p.L1108dup | In Frame Ins (INS) | VAF 14/24 reads (58%) | called by mutect2, pindel, varscan2
- MAST4 | c.3863_3868del p.N1288_S1290delinsT (on ENST00000403625 / NM_001164664.2; = p.N1099_S1101delinsT on NM_015183.3) | In Frame Del (DEL) | VAF 26/33 reads (79%) | called by mutect2, pindel*, varscan2*
- MGA | c.498del p.H167Ifs*49 | Frame Shift Del (DEL) | VAF 145/414 reads (35%) | called by mutect2, pindel, varscan2
- MGA | c.7822_7851del p.K2608_V2617del (on ENST00000219905 / NM_001164273.1; = p.K2399_V2408del on NM_001080541.2) | In Frame Del (DEL) | VAF 24/191 reads (13%) | called by mutect2, pindel
- MRPS21 | c.80_83+6del p.X27_splice | Splice Site (DEL) | VAF 20/52 reads (38%) | called by mutect2, pindel, varscan2
- NDUFA4L2 | c.201del p.Q67Hfs*14 | Frame Shift Del (DEL) | VAF 21/52 reads (40%) | called by mutect2, pindel*, varscan2*
- NKD1 | c.114_115insAAGTGGATC p.I38_G39insKWI | In Frame Ins (INS) | VAF 7/21 reads (33%) | called by mutect2, varscan2
- NOXA1 | c.199_203del p.K67Hfs*26 | Frame Shift Del (DEL) | VAF 9/78 reads (12%) | called by mutect2, pindel, varscan2
- OGG1 | c.37dup p.H13Pfs*20 | Frame Shift Ins (INS) | VAF 36/62 reads (58%) | called by pindel, varscan2
- OR1L8 | c.107_113del p.Y36Sfs*3 | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | called by mutect2, pindel
- PLEKHA8 | c.597+5_597+6dup | Splice Region (INS) | VAF 46/119 reads (39%) | called by mutect2, pindel, varscan2
- PRPSAP2 | c.1052_1077del p.R351Lfs*10 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | called by mutect2, pindel, varscan2
- PSMD12 | c.813dup p.L272Tfs*9 | Frame Shift Ins (INS) | VAF 14/63 reads (22%) | called by mutect2, pindel, varscan2
- PTEN | c.499dup p.T167Nfs*13 | Frame Shift Ins (INS) | VAF 43/98 reads (44%) | called by pindel, varscan2
- PTK6 | c.1160_1161del p.P387Lfs*8 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- PYGM | c.2304_2308del p.H768Qfs*4 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- RABGAP1L | c.1503_1506dup p.K503Vfs*2 | Frame Shift Ins (INS) | VAF 30/78 reads (38%) | called by mutect2, pindel, varscan2
- RERE | c.4682_4684del p.E1561del | In Frame Del (DEL) | VAF 28/66 reads (42%) | called by pindel, varscan2
- RTN4RL2 | c.696_697dup p.Y233Sfs*55 | Frame Shift Ins (INS) | VAF 24/54 reads (44%) | called by mutect2, varscan2
- SEZ6L2 | c.2489-1_2491dup p.T831Sfs*70 (on ENST00000308713 / NM_001114099.3; = p.T774Sfs*70 on NM_012410.4) | Frame Shift Ins (INS) | VAF 31/87 reads (36%) | called by mutect2, pindel, varscan2
- SGO1 | c.1579_1580dup p.P528Hfs*34 (on ENST00000263753 / NM_001012410.5; = p.P259Hfs*34 on NM_138484.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 17/25 reads (68%) | called by mutect2, pindel, varscan2
- SI | c.298_301del p.D100Lfs*19 | Frame Shift Del (DEL) | VAF 38/68 reads (56%) | called by mutect2, pindel, varscan2
- SLC30A4 | c.1222_1223del p.I408Sfs*20 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- SLITRK6 | c.599_639del p.Y200Sfs*12 | Frame Shift Del (DEL) | VAF 46/158 reads (29%) | called by mutect2, pindel
- SPTBN4 | c.5924_5927dup p.V1977Ifs*15 | Frame Shift Ins (INS) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- STYXL2 | c.269_272dup p.L92Afs*16 | Frame Shift Ins (INS) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- SUGT1P4-STRA6LP | n.1033G>C | Splice Region (SNP) | VAF 43/104 reads (41%) | called by muse, mutect2, varscan2
- SYNRG | c.1292dup p.G432Wfs*8 | Frame Shift Ins (INS) | VAF 23/65 reads (35%) | called by mutect2, pindel, varscan2
- TCF20 | c.4151_4182del p.D1384Gfs*10 | Frame Shift Del (DEL) | VAF 49/68 reads (72%) | called by mutect2, pindel
- TENT2 | c.1417_1426del p.S473Lfs*2 | Frame Shift Del (DEL) | VAF 32/43 reads (74%) | called by mutect2, pindel, varscan2
- TENT4B | c.1558_1559dup p.D520Efs*10 (on ENST00000561678 / NM_001365323.2; = p.D505Efs*10 on NM_001040284.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 50/158 reads (32%) | called by mutect2, pindel, varscan2
- TF | c.1474dup p.H492Pfs*5 | Frame Shift Ins (INS) | VAF 162/324 reads (50%) | called by mutect2, pindel, varscan2
- TM4SF19 | c.402_403dup p.T135Rfs*111 | Frame Shift Ins (INS) | VAF 62/127 reads (49%) | called by mutect2, pindel, varscan2
- TMTC2 | c.572_573del p.T191Sfs*9 | Frame Shift Del (DEL) | VAF 33/46 reads (72%) | called by mutect2, pindel*, varscan2*
- TTC7B | c.332_346del p.G111_E115del | In Frame Del (DEL) | VAF 29/95 reads (31%) | called by mutect2, pindel, varscan2
- TTF2 | c.3269_3269+6del p.X1090_splice | Splice Site (DEL) | VAF 49/159 reads (31%) | called by mutect2, pindel, varscan2
- UBXN1 | c.110_112del p.D37_W38delinsG | In Frame Del (DEL) | VAF 12/29 reads (41%) | called by mutect2, pindel, varscan2
- VAV1 | c.1268_1271dup p.F425Cfs*12 | Frame Shift Ins (INS) | VAF 31/58 reads (53%) | called by mutect2, pindel, varscan2
- WRNIP1 | c.1595dup p.L533Tfs*40 | Frame Shift Ins (INS) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- FAT2 | c.7947G>T p.L2649= | Silent (SNP) | VAF 5/87 reads (6%) | catalogued as COSV99943507; called by muse, mutect2
- MGAT1 | c.1227G>A p.S409= | Silent (SNP) | VAF 26/35 reads (74%) | catalogued as rs763529224, COSV57134331; called by muse, varscan2
- OR4A5 | c.120C>T p.N40= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs757566699, COSV100157195; called by muse, mutect2, varscan2
- PKD1 | c.7227G>A p.T2409= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs527865750, COSV51912852; called by muse, varscan2
- VANGL2 | c.429G>A p.T143= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs769374648, COSV100925587; called by muse, mutect2, varscan2
- AC024940.1 | n.3196del | RNA (DEL) | VAF 40/62 reads (65%) | called by mutect2, pindel, varscan2
- AP000769.5 | chr11:65500919 del TTTTTCAGGCTTA | 5'Flank (DEL) | VAF 21/55 reads (38%) | called by mutect2, pindel, varscan2
- CYGB | c.-2T>A | 5'UTR (SNP) | VAF 20/35 reads (57%) | catalogued as COSV99506193; called by muse, mutect2, varscan2
- EIF2B2 | c.-18_-2del | 5'UTR (DEL) | VAF 11/22 reads (50%) | called by mutect2, pindel, varscan2
- SRSF6 | c.257-531dup | Intron (INS) | VAF 30/96 reads (31%) | called by mutect2, pindel, varscan2
- TRIM8 | c.*667_*670dup | 3'UTR (INS) | VAF 18/30 reads (60%) | called by mutect2, pindel, varscan2
